Surgical pathology report (de-identified scan), TCGA case TCGA-61-2104, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2104-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –

- A. ADIPOSE TISSUE WITH EXTENSIVE INFLAMMATORY INFILTRATE AND MESOTHELIAL REACTION.
- B. NO DEFINITIVE TUMOR IDENTIFIED.

PART 2: RIGHT TUBE AND OVARY, SALPINGO-OOPHORECTOMY –

- A. MODERATELY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA.
- B. SEGMENT OF FALLOPIAN TUBE WITH ADHESION.

PART 3: LEFT OVARY AND FALLOPIAN TUBE, LEFT SALPINGO-OOPHORECTOMY –

- A. FOCAL PAPILLARY SEROUS CARCINOMA ARISING IN A TUMOR OF LOWER MALIGNANT POTENTIAL.
- B. FALLOPIAN TUBE NOT REMARKABLE.

PART 4: CUL-DE-SAC TUMOR, EXCISIONAL BIOPSY –

FIBROADIPOSE TISSUE POSITIVE FOR MODERATELY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA.

PART 5: UTERUS WITHOUT ADNEXA, 430 GM., TOTAL ABDOMINAL HYSTERECTOMY –

- A. CHRONIC CYSTIC CERVICITIS.
- B. ENDOMETRIUM AND BASALIS.
- C. LEIOMYOMAS UP TO 5 CM.

PART 6: SOFT UMBILICAL NODULE, EXCISIONAL BIOPSY –
BENIGN FIBROADIPOSE TISSUE.

PART 10: LEFT PERICOLIC GUTTER, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 11: LEFT PELVIC PERITONEUM, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 12: RIGHT PERICOLIC GUTTER, BIOPSY –
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 13: RIGHT PELVIC PERITONEUM, BIOPSY –
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 14: RIGHT DIAPHRAGM, BIOPSY –
ADIPOSE TISSUE AND STRIATED MUSCLE, NEGATIVE FOR TUMOR.

PART 15: BLADDER PERITONEUM #1, BIOPSY –
ADIPOSE TISSUE NEGATIVE FOR TUMOR.

PART 16: BLADDER PERITONEUM #2, BIOPSY –
FIBROMUSCULAR AND ADIPOSE TISSUE NEGATIVE FOR TUMOR.

PART 17: OMENTUM #1, BIOPSY –
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 18: OMENTUM #2, BIOPSY –
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 19: OMENTUM #3, BIOPSY –
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 20: OMENTUM #4, E BIOPSY –
ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file a0bea6c5-f046-4f3e-87f1-35850c28682f (TCGA-61-2104.38D2E115-EC9A-40E5-BFA0-30FB1DB60691.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).